Somatic mutation profile of tumor specimen ALCH-B01D-TTP1-A (aliquot ALCH-B01D-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B01D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.9 years (23,352 days).
Specimen ALCH-B01D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4af42a90-7bdc-4a29-a96f-c2610787b746.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01D-NB1-A (Blood Derived Normal), aliquot ALCH-B01D-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17df3916-f273-4016-b5b6-d8993fedcf7a

The open-access MAF lists 608 somatic variants for this specimen: 391 protein-altering or splice-affecting, 139 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 336, Silent 139, Intron 32, Nonsense Mutation 25, RNA 18, 5'UTR 10, Frame Shift Del 10, 3'UTR 9, Splice Region 7, Splice Site 7, 5'Flank 5, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 232/422 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYO18B | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 44/151 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs753198702, COSV100123566, COSV59124221; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 100/297 reads (34%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55595275, COSV55596464, COSV99792434; called by muse, mutect2, varscan2
- ABCB5 | c.1759C>T p.R587* (on ENST00000404938 / NM_001163941.2; = p.R142* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 81/255 reads (32%) | catalogued as rs746177833, COSV51704222, COSV51720176; called by muse, mutect2, varscan2
- ACTG2 | c.317T>A p.L106H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV61828257; called by muse, mutect2
- ADAM23 | c.2076C>A p.C692* | Nonsense Mutation (SNP) | VAF 37/182 reads (20%) | catalogued as COSV100008861; called by muse, mutect2, varscan2
- ADAMTS13 | c.3377G>T p.W1126L | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV52469205; called by muse, mutect2, varscan2
- ADAMTS4 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63489302; called by muse, mutect2, varscan2
- ADCY8 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99651467; called by muse, mutect2, varscan2
- ADGRL3 | c.1616C>T p.S539F (on ENST00000506720 / NM_001322402.2; = p.S471F on NM_015236.6) | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as rs758149971; called by muse, mutect2, varscan2
- AEBP1 | c.1552C>A p.R518S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56259415; called by muse, mutect2, varscan2
- AFF2 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV60677128; called by muse, mutect2, varscan2
- AK4 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs778627421, COSV59196670; called by muse, mutect2, varscan2
- ARRB1 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100758107, COSV63577073; called by mutect2, varscan2
- ASB5 | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV56669714; called by muse, mutect2, varscan2
- ATM | c.5756A>C p.Q1919P | Missense Mutation (SNP) | VAF 110/496 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565486302, COSV53785003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.5858C>A p.T1953K | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM090511, COSV53753678; called by muse, mutect2
- AVPR1A | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as rs1312839078; called by muse, mutect2, varscan2
- C11orf21 | c.368G>T p.R123L (on ENST00000381153 / NM_001329958.2; = p.R169L on NM_001142946.3) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV51721374; called by muse, mutect2, varscan2
- C7 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255838743; called by muse, mutect2, varscan2
- CAMKMT | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as rs539533020; called by muse, mutect2, varscan2
- CCDC54 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV53760002; called by muse, mutect2, varscan2
- CD109 | c.3712G>T p.V1238L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54658024; called by muse, mutect2
- CDKL3 | c.1391G>C p.R464P | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV54739704; called by muse, mutect2, varscan2
- CNTNAP5 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs369688023; called by muse, mutect2, varscan2
- CSMD3 | c.9111G>T p.L3037F (on ENST00000297405 / NM_001363185.1; = p.L2868F on NM_052900.3) | Missense Mutation (SNP) | VAF 137/496 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.947); catalogued as COSV99843196; called by muse, mutect2, varscan2
- CTNNA3 | c.2600C>A p.T867K | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV65524040; called by muse, mutect2, varscan2
- DCDC1 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60842176; called by muse, mutect2
- DECR1 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV55170110; called by muse, mutect2, varscan2
- DIS3L | c.265C>T p.Q89* (on ENST00000319212 / NM_001143688.3; = p.Q6* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/157 reads (15%) | catalogued as COSV59911003, COSV59912617; called by muse, mutect2, varscan2
- DUSP22 | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60531462; called by muse, mutect2
- ELF1 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1377566722; called by muse, mutect2, varscan2
- ERCC6L2 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs1457716602; called by muse, mutect2, varscan2
- FBXL4 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM138677; called by muse, mutect2, varscan2
- FBXW12 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 63/264 reads (24%) | catalogued as rs771265112, COSV56483076; called by muse, mutect2, varscan2
- FSIP2 | c.7799C>A p.A2600E | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100555893; called by muse, mutect2, varscan2
- GCM2 | c.1058C>A p.A353D | Missense Mutation (SNP) | VAF 103/411 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV65275390; called by muse, mutect2, varscan2
- GPRIN1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs764550111, COSV99992125; called by muse, mutect2, varscan2
- GUCY1A1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as rs766618110; called by muse, mutect2, varscan2
- HOXB13 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1016398275, COSV51704758; ClinVar: uncertain significance; called by muse, mutect2
- HOXB4 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1455131343; called by muse, mutect2, varscan2
- IRGM | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs1322491414; called by muse, mutect2, varscan2
- KCNU1 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV67757828; called by muse, mutect2, varscan2
- KIAA1614 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV62551541; called by muse, mutect2, varscan2
- KRTAP4-12 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs746329574, COSV67458153; called by muse, mutect2, varscan2
- LAMB1 | c.2387C>A p.P796H | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV55965996; called by muse, mutect2, varscan2
- LMOD2 | c.910C>A p.H304N | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71755768; called by mutect2, varscan2
- LPA | c.4156C>A p.Q1386K | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.892); catalogued as COSV60307629; called by muse, mutect2, varscan2
- LTBP3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs747090910; called by muse, mutect2, varscan2
- LYPD6B | c.479G>A p.R160K (on ENST00000409029 / NM_001317004.1; = p.R184K on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1415322740, COSV54518026; called by muse, varscan2
- MAPK4 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV68541111; called by muse, mutect2, varscan2
- MELK | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53197366; called by muse, mutect2, varscan2
- MGA | c.6343G>T p.E2115* (on ENST00000219905 / NM_001164273.1; = p.E1906* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as COSV54961690; called by muse, mutect2, varscan2
- MICB | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1374338147; called by muse, mutect2, varscan2
- MMP26 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56172844; called by muse, mutect2, varscan2
- MUC16 | c.2465A>C p.H822P | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV67498125; called by muse, mutect2, varscan2
- MUC17 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs749803432; called by muse, mutect2, varscan2
- MUC22 | c.3368C>T p.S1123F | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0); catalogued as rs1562614016; called by muse, mutect2, varscan2
- NCKAP5 | c.4173C>A p.F1391L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100490552; called by muse, mutect2, varscan2
- NPAP1 | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV61506873; called by muse, mutect2
- NRK | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99687463; called by muse, mutect2, varscan2
- NTRK3 | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 48/350 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV62308222; called by muse, mutect2, varscan2
- NYAP2 | c.1961G>T p.*654Lext*19 | Nonstop Mutation (SNP) | VAF 32/144 reads (22%) | catalogued as COSV56000535; called by muse, mutect2, varscan2
- OR10H2 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59946368; called by muse, mutect2, varscan2
- OR10V1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV55700023; called by muse, mutect2, varscan2
- OR2AK2 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV63551806; called by muse, mutect2, varscan2
- OR2G6 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58575380; called by muse, mutect2, varscan2
- OR2W3 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV64457957; called by muse, varscan2
- OR4C11 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs193033371, COSV56354179; called by muse, mutect2
- OR4K15 | c.128G>T p.S43I (on ENST00000305051; = p.S19I on NM_001005486.1) | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100521105; called by muse, mutect2
- OR52B4 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 37/235 reads (16%) | catalogued as rs1340411145; called by muse, mutect2, varscan2
- OR5B2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as rs367965186; called by muse, mutect2, varscan2
- OR5D13 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs749525915, COSV62335019; called by muse, mutect2, varscan2
- OR5D14 | c.592C>G p.H198D | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59458347; called by muse, mutect2, varscan2
- OTOP1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99588054; called by muse, mutect2, varscan2
- PAK5 | c.2021G>T p.R674L | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV62021757; called by muse, mutect2, varscan2
- PAX4 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 101/560 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as COSV58387755; called by muse, mutect2, varscan2
- PCDH8 | c.3116G>T p.G1039V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100131194, COSV58814448; called by muse, mutect2, varscan2
- PCDH8 | c.3019C>A p.Q1007K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV100131509; called by muse, mutect2, varscan2
- PCDHB12 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs781824876; called by muse, mutect2, varscan2
- PCDHB4 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781808436; called by muse, mutect2, varscan2
- PCDHB8 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 76/458 reads (17%) | catalogued as COSV50762962; called by muse, mutect2, varscan2
- PCDHGC3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452697214, COSV52744109; called by muse, mutect2, varscan2
- PCLO | c.7045G>A p.A2349T | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV61653532; called by muse, mutect2, varscan2
- PCLO | c.5846G>T p.G1949V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61653040; called by muse, mutect2, varscan2
- PDGFRB | c.2765G>T p.R922L | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55800673; called by muse, mutect2, varscan2
- PDIA4 | c.1432G>T p.A478S (on ENST00000286091 / NM_001371244.1; = p.A477S on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as COSV99618424; called by muse, mutect2, varscan2
- PEG3 | c.2383G>T p.G795W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55646370; called by muse, mutect2, varscan2
- PGAP4 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66387849; called by muse, mutect2, varscan2
- PTGDR2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs759678740; called by muse, mutect2, varscan2
- RABL3 | c.316T>G p.L106V | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1407548864, COSV99846672; called by muse, mutect2, varscan2
- RIMS2 | c.3089C>A p.P1030Q (on ENST00000666250 / NM_001348490.2; = p.P838Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV99179367; called by muse, mutect2, varscan2
- RNF31 | c.495+8G>A | Splice Region (SNP) | VAF 25/146 reads (17%) | catalogued as rs1306360568; called by muse, mutect2, varscan2
- RP1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs750701446, COSV55117948, COSV55126181; called by muse, mutect2, varscan2
- RPGR | c.1513A>G p.I505V | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as CD972433; called by muse, mutect2, varscan2
- RYR3 | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV101211703; called by muse, mutect2
- SFXN1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.61); catalogued as rs1408816566; called by muse, mutect2, varscan2
- SKOR2 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1279001608; called by muse, mutect2, varscan2
- SLC12A1 | c.1879del p.A627Qfs*16 | Frame Shift Del (DEL) | VAF 35/345 reads (10%) | catalogued as rs1295566242, COSV66791352; called by mutect2, pindel, varscan2
- SLC26A3 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60638730; called by mutect2, varscan2
- SMARCA1 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100946527; called by muse, mutect2, varscan2
- SMARCA2 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61807762; called by muse, mutect2, varscan2
- SORCS1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53902470; called by muse, mutect2, varscan2
- STK38 | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs762637869, COSV57707426; called by muse, mutect2, varscan2
- TADA3 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs1457774524; called by muse, mutect2, varscan2
- THSD7A | c.1563G>T p.W521C | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70264996; called by muse, varscan2
- TMC1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 51/418 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as rs145102585; called by muse, mutect2, varscan2
- TMEM130 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV59558107; called by muse, mutect2, varscan2
- TMPRSS15 | c.2708T>C p.V903A | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.044); catalogued as CD020086; called by muse, mutect2, varscan2
- TMPRSS15 | c.2054C>A p.T685K | Missense Mutation (SNP) | VAF 41/385 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.087); catalogued as COSV53034292, COSV53035773; called by muse, mutect2, varscan2
- TPO | c.2515G>A p.V839I | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs146351101, CM024371; called by muse, mutect2, varscan2
- TRIM2 | c.1117G>A p.D373N (on ENST00000437508; = p.D400N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1341638291, COSV100107906; called by muse, mutect2
- UHRF1BP1L | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759447962; called by muse, mutect2, varscan2
- USP29 | c.2571C>A p.N857K | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54139718; called by muse, mutect2
- USP29 | c.2572G>T p.D858Y | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54140150, COSV54144117; called by muse, mutect2
- WDR86 | c.727-5C>T | Splice Region (SNP) | VAF 11/91 reads (12%) | catalogued as rs749805090; called by muse, mutect2, varscan2
- WSCD1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100496561; called by muse, mutect2, varscan2
- ZFPM2 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 152/570 reads (27%) | catalogued as COSV65873858; called by muse, mutect2, varscan2
- ZNF92 | c.1009G>T p.G337W (on ENST00000328747 / NM_152626.4; = p.G268W on NM_007139.4) | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100165966; called by muse, mutect2, varscan2
- ABI1 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, varscan2
- AC068580.4 | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSBG1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ADGRB1 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ADGRG7 | c.113G>T p.R38I | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AKAP3 | c.1487A>C p.Y496S | Missense Mutation (SNP) | VAF 85/152 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ALDOB | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 74/614 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALLC | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ANAPC1 | c.5737G>A p.E1913K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- ANGPT4 | c.1252G>T p.G418W | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK2 | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1887G>T p.R629S | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD30B | c.2823A>T p.A941= | Splice Region (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- ANKRD30BL | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36 | c.1392A>T p.E464D | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- AQP12A | c.438del p.V147Cfs*17 | Frame Shift Del (DEL) | VAF 2/14 reads (14%) | called by mutect2, varscan2
- ARHGEF4 | c.-108-3C>T | Splice Region (SNP) | VAF 70/263 reads (27%) | called by muse, mutect2, varscan2
- ATP11B | c.2852G>T p.S951I | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- ATPSCKMT | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AZIN2 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- BCHE | c.1271A>T p.Y424F | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2
- C4orf17 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CABS1 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1B | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CACNA1H | c.2884T>C p.W962R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNG8 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.972); called by muse, mutect2
- CALCA | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CAMK2D | c.685G>T p.G229* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- CARMIL2 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC180 | c.2232G>T p.E744D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCDC85A | c.884A>T p.H295L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CD163 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CD163L1 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 138/511 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH13 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH23 | c.2359C>A p.L787M | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- CDHR1 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPH | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- CHFR | c.340C>G p.H114D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- CHST5 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHST8 | c.733T>A p.L245M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CIITA | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CNST | c.1934G>T p.R645I | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CNTNAP2 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- COL11A1 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL15A1 | c.3432G>T p.M1144I | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- COL6A5 | c.3977G>T p.R1326M | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CPA1 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1D | c.967A>C p.T323P | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSTA | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTSC | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 75/571 reads (13%) | called by muse, mutect2, varscan2
- CYP4V2 | c.1565C>A p.A522E | Missense Mutation (SNP) | VAF 96/484 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, varscan2
- CYSLTR2 | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- CYYR1 | c.249C>A p.C83* | Nonsense Mutation (SNP) | VAF 48/236 reads (20%) | called by muse, mutect2, varscan2
- DAB2 | c.2067G>T p.K689N | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAB2 | c.1309A>T p.T437S | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- DCAF1 | c.3414C>G p.I1138M | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DLL4 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- DMBT1 | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.681); called by muse, mutect2
- DMRTB1 | c.45G>C p.R15S | Missense Mutation (SNP) | VAF 43/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH6 | c.677A>T p.E226V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DNHD1 | c.11681C>A p.P3894Q | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- DPY19L2 | c.1619C>A p.T540K | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DSCAML1 | c.2079C>A p.D693E (on ENST00000321322; = p.D633E on NM_020693.4) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DTNA | c.1699C>A p.H567N | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- EDIL3 | c.940T>A p.C314S | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF5B | c.174C>G p.I58M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2
- EMILIN3 | c.2173T>A p.W725R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ENO3 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L2 | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EPHB6 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERVV-2 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 66/245 reads (27%) | called by muse, mutect2, varscan2
- ETNPPL | c.1083-1G>C p.X361_splice | Splice Site (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- EVI5L | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- FAM71C | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 103/347 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- FAM98A | c.980A>T p.D327V | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- FANCM | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FASN | c.4764_4765delinsT p.P1589Qfs*11 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | called by pindel, varscan2*
- FAT3 | c.10754C>A p.T3585K | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- FBF1 | c.3+1G>C p.X1_splice | Splice Site (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- FER1L6 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- FNBP1 | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- FZR1 | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- FZR1 | c.470+1G>T p.X157_splice | Splice Site (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- GDF2 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- GDPD4 | c.1401C>G p.F467L | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GGNBP2 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- GHRHR | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- GPR149 | c.2009C>A p.A670D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR78 | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIA4 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTF3C1 | c.4075G>T p.D1359Y | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- HCN1 | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- HCRTR2 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- HIPK1 | c.2771G>T p.S924I | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- HLTF | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- HMCN2 | c.5624C>T p.A1875V | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMG20A | c.237+8G>T | Splice Region (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- HOGA1 | c.468+7G>T | Splice Region (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- HOXD13 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HSPA1L | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HUWE1 | c.12335G>C p.R4112P | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IARS2 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, varscan2
- IGLV1-44 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IQUB | c.630_633dup p.V212Sfs*10 | Frame Shift Ins (INS) | VAF 24/214 reads (11%) | called by mutect2, pindel
- IRX6 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ITGAM | c.2736C>A p.N912K (on ENST00000648685 / NM_001145808.2; = p.N911K on NM_000632.4) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KALRN | c.586A>C p.S196R | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA0319 | c.2750G>T p.C917F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KIN | c.114+1G>C p.X38_splice | Splice Site (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2
- KLHL31 | c.738G>C p.K246N | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KMT2C | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KNG1 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- KRT4 | c.263_264insTGT p.G88_F89insV | In Frame Ins (INS) | VAF 37/122 reads (30%) | called by mutect2, varscan2*
- KYNU | c.829-2A>T p.X277_splice | Splice Site (SNP) | VAF 46/259 reads (18%) | called by muse, mutect2, varscan2
- LAMA3 | c.5033G>T p.G1678V (on ENST00000313654 / NM_198129.4; = p.G69V on NM_000227.6) | Missense Mutation (SNP) | VAF 53/442 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- LATS2 | c.2579G>C p.R860T | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LAX1 | c.446A>T p.E149V | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- LBP | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LGSN | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 71/575 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIN9 | c.628del p.D210Ifs*8 (on ENST00000366808 / NM_001270410.2; = p.D155Ifs*8 on NM_173083.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/141 reads (28%) | called by mutect2, pindel, varscan2
- LOXHD1 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2
- LRP12 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.2721C>A p.S907R (on ENST00000651989 / NM_001370785.2; = p.S874R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC74B | c.1037A>T p.N346I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- LRRIQ4 | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MAGEB6B | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.238); called by muse, mutect2
- MAGEB6B | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MANEA | c.544+4A>T | Splice Region (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- MAP3K20 | c.1241dup p.L414Ffs*9 | Frame Shift Ins (INS) | VAF 42/248 reads (17%) | called by mutect2, pindel, varscan2
- MAP6 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MAPK4 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- METTL4 | c.1250A>T p.H417L | Missense Mutation (SNP) | VAF 126/362 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLEC | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MMP12 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.161); called by muse, mutect2
- MMP9 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MOCOS | c.2501G>C p.S834T | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MRC1 | c.3356C>A p.A1119E | Missense Mutation (SNP) | VAF 70/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH9 | c.1628C>A p.P543Q | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MTAP | c.348-1G>T p.X116_splice | Splice Site (SNP) | VAF 26/170 reads (15%) | called by muse, varscan2
- MUC16 | c.41602C>T p.P13868S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC16 | c.36820A>T p.S12274C | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC17 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MYCBP2 | c.7254G>T p.L2418F (on ENST00000357337; = p.L2456F on NM_015057.5) | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MYH2 | c.3846G>T p.Q1282H | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYH9 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MYO1D | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYOZ2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- NCAPD2 | c.1097T>C p.L366S | Missense Mutation (SNP) | VAF 202/487 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCOA1 | c.4065G>T p.Q1355H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NCOA6 | c.1237A>T p.R413W | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NELL2 | c.2220G>T p.E740D | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NID2 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- NKAPL | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLE1 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, varscan2
- NPY2R | c.645T>A p.Y215* | Nonsense Mutation (SNP) | VAF 112/611 reads (18%) | called by muse, mutect2, varscan2
- NRXN3 | c.2862G>T p.W954C (on ENST00000335750 / NM_001330195.2; = p.W581C on NM_004796.6) | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NSMAF | c.1090G>T p.G364W | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFM3 | c.247A>T p.S83C (on ENST00000338858 / NM_001288821.1; = p.S63C on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, varscan2
- OLIG1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); called by muse, varscan2
- OR14J1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L5 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR2T1 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- OR3A3 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by mutect2, varscan2
- OR51D1 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR8A1 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OSBPL11 | c.1930A>T p.S644C | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OTC | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PABPC1 | c.1397T>A p.M466K | Missense Mutation (SNP) | VAF 38/605 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- PACSIN2 | c.618_622del p.K207* | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel
- PCDHB10 | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PCDHGA3 | c.1728G>T p.E576D | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PCDHGA3 | c.2263C>A p.H755N | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PCLO | c.5116G>A p.D1706N | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PDCD6IP | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGAP1 | c.2599G>T p.G867* | Nonsense Mutation (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- PITX2 | c.226G>T p.A76S (on ENST00000354925 / NM_001204397.1; = p.A83S on NM_000325.6) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PJA2 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PKHD1 | c.8951-1G>T p.X2984_splice | Splice Site (SNP) | VAF 51/244 reads (21%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, varscan2
- POLE | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- POLR1D | c.95_100dup p.A32_A33dup | In Frame Ins (INS) | VAF 32/183 reads (17%) | called by mutect2, varscan2
- POSTN | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2
- POTEJ | c.1516A>T p.K506* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PROSER1 | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PSG5 | c.651T>A p.C217* | Nonsense Mutation (SNP) | VAF 50/202 reads (25%) | called by muse, mutect2, varscan2
- PTCD2 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- R3HDM1 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAPGEF5 | c.975G>T p.L325F (on ENST00000401957 / NM_001367602.2; = p.L628F on NM_012294.5) | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RIMS1 | c.1911A>T p.K637N | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPOR2 | c.947A>T p.Y316F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- RND3 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- RTTN | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RUNX1T1 | c.1703C>A p.S568Y (on ENST00000265814 / NM_001198628.1; = p.S541Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- RYR2 | c.8950T>C p.S2984P | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- RYR2 | c.11392C>G p.Q3798E | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RYR3 | c.757G>C p.A253P | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- RYR3 | c.8133G>T p.Q2711H (on ENST00000389232; = p.Q2712H on NM_001036.6) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- SACM1L | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SERPINA6 | c.1148del p.F383Sfs*4 | Frame Shift Del (DEL) | VAF 39/375 reads (10%) | called by mutect2, pindel, varscan2
- SERPINB4 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SGMS2 | c.723del p.E242Nfs*12 | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | called by mutect2, pindel
- SIRPG | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLC17A4 | c.1184C>G p.T395S | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC22A25 | c.986A>T p.E329V | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SLC22A25 | c.912C>A p.H304Q | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SLC25A12 | c.1796A>T p.E599V | Missense Mutation (SNP) | VAF 103/522 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC25A24 | c.184A>C p.K62Q | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by mutect2, varscan2
- SLIT1 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SMARCA2 | c.3573G>C p.K1191N | Missense Mutation (SNP) | VAF 101/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SMC1B | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SMPD4 | c.2504G>T p.G835V (on ENST00000409031 / NM_017951.4; = p.G806V on NM_017751.4) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SMPDL3B | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SNX30 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2
- SORBS2 | c.664A>C p.I222L (on ENST00000284776 / NM_021069.5; = p.I268L on NM_003603.6) | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SOS2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SPAG16 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SPAG16 | c.1553G>C p.G518A | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SPAG6 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2
- SPATA16 | c.210A>T p.K70N | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SPATA31A6 | c.1256T>A p.L419H | Missense Mutation (SNP) | VAF 39/661 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPINK5 | c.275del p.P92Qfs*4 | Frame Shift Del (DEL) | VAF 78/428 reads (18%) | called by mutect2, pindel, varscan2
- SPRR2D | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 34/456 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SSC4D | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSTR4 | c.1077C>A p.C359* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, varscan2
- SYNGR4 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAF7L | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- TBX15 | c.341A>T p.Q114L (on ENST00000369429 / NM_001330677.2; = p.Q8L on NM_152380.3) | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TCTEX1D1 | c.414C>G p.N138K | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD12 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEP1 | c.6484G>T p.V2162L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.872); called by muse, mutect2
- TEX15 | c.5545C>A p.P1849T (on ENST00000256246; = p.P2232T on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, varscan2
- TFAP2B | c.1236del p.A413Rfs*21 | Frame Shift Del (DEL) | VAF 69/276 reads (25%) | called by mutect2, pindel, varscan2
- THSD1 | c.1069G>T p.G357W | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM31 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 74/170 reads (44%) | called by muse, mutect2, varscan2
- TMEM38B | c.728T>A p.M243K | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TMEM38B | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMX3 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TOPAZ1 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAV12-1 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRAV24 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRGV3 | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 103/457 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRIM64C | c.360C>A p.H120Q | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TSHZ3 | c.761G>T p.W254L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- TTC37 | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 118/519 reads (23%) | called by muse, mutect2, varscan2
- TTF1 | c.1808_1811del p.I603Tfs*25 | Frame Shift Del (DEL) | VAF 55/352 reads (16%) | called by mutect2, pindel, varscan2
- TTN | c.18475G>C p.D6159H (on ENST00000591111; = p.D5232H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | PolyPhen possibly damaging (0.891); called by muse, mutect2
- UBE4B | c.3874G>C p.A1292P (on ENST00000343090 / NM_001105562.3; = p.A1163P on NM_006048.5) | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- UNK | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- VWA5B2 | c.2210C>A p.A737D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- VWA8 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- WASF3 | c.736A>T p.T246S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.147); called by muse, varscan2
- WDFY1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.7801C>G p.Q2601E | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- WDR97 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNT10A | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, varscan2
- WNT16 | c.746T>G p.L249W (on ENST00000222462 / NM_057168.2; = p.L239W on NM_016087.2) | Missense Mutation (SNP) | VAF 110/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP1 | c.5183C>T p.S1728F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- XIRP2 | c.7880G>T p.R2627M (on ENST00000628543; = p.R2802M on NM_152381.6) | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ZBED1 | c.1212C>G p.F404L | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZCCHC17 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF239 | c.1046G>C p.C349S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF33B | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF33B | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF521 | c.995A>T p.H332L | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ZNF536 | c.2914C>T p.Q972* | Nonsense Mutation (SNP) | VAF 47/238 reads (20%) | called by muse, mutect2, varscan2
- ZNF682 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF98 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ZSCAN23 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- ZSWIM5 | c.1085A>T p.N362I | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- AC024598.1 | c.1197C>G p.V399= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.306A>C p.V102= | Silent (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- ADD2 | c.1917C>A p.P639= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV100034597, COSV52459154; called by muse, mutect2
- ADGRB3 | c.3873G>A p.G1291= | Silent (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- ADGRL2 | c.414G>T p.G138= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- AHCYL2 | c.135G>T p.A45= | Silent (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- ANKRD50 | c.3276G>A p.Q1092= | Silent (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2
- ARHGAP31 | c.1122C>T p.F374= | Silent (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2, varscan2
- ARMH3 | c.2013G>T p.L671= | Silent (SNP) | VAF 24/224 reads (11%) | called by muse, mutect2, varscan2
- ASPHD2 | c.246G>A p.Q82= | Silent (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- ATP11B | c.2850T>C p.I950= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV60034662; called by muse, mutect2
- ATP7B | c.1761G>T p.T587= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV99666662; called by muse, mutect2
- C17orf67 | c.60C>T p.T20= | Silent (SNP) | VAF 62/379 reads (16%) | catalogued as rs748703650, COSV67375422; called by muse, mutect2, varscan2
- C2CD3 | c.177A>T p.V59= | Silent (SNP) | VAF 55/440 reads (13%) | called by muse, mutect2, varscan2
- CACNA1H | c.2637C>T p.G879= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, varscan2
- CACNB2 | c.1392C>A p.T464= (on ENST00000324631 / NM_201596.3; = p.T409= on NM_000724.4) | Silent (SNP) | VAF 29/194 reads (15%) | catalogued as COSV56621773; called by muse, mutect2, varscan2
- CADPS | c.261C>A p.G87= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs1247012674; called by muse, mutect2, varscan2
- CAMSAP2 | c.2997G>A p.L999= (on ENST00000236925 / NM_001297707.2; = p.L988= on NM_203459.3) | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- CATSPERD | c.1512A>G p.T504= | Silent (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- CDV3 | c.87G>C p.A29= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- CER1 | c.705G>T p.L235= | Silent (SNP) | VAF 46/327 reads (14%) | called by muse, mutect2, varscan2
- CLDN11 | c.474G>T p.L158= | Silent (SNP) | VAF 78/422 reads (18%) | called by muse, mutect2, varscan2
- CNTRL | c.3582C>T p.P1194= | Silent (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- CPZ | c.363C>T p.I121= (on ENST00000360986 / NM_001014447.3; = p.I110= on NM_003652.3) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1397556747; called by muse, varscan2
- CT47B1 | c.81G>T p.A27= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs755187963; called by muse, mutect2, varscan2
- CYP2A6 | c.354C>T p.F118= | Silent (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- DARS2 | c.72G>A p.P24= | Silent (SNP) | VAF 77/606 reads (13%) | called by muse, mutect2, varscan2
- DDX53 | c.240T>A p.T80= | Silent (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- DENND4B | c.615G>A p.K205= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- DLG2 | c.1348C>T p.L450= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as rs775296170; called by muse, mutect2, varscan2
- DLL3 | c.1389G>T p.R463= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as COSV52696047; called by muse, mutect2, varscan2
- DMRT1 | c.777C>A p.G259= | Silent (SNP) | VAF 68/238 reads (29%) | called by muse, mutect2, varscan2
- DNAH7 | c.7932G>T p.V2644= | Silent (SNP) | VAF 38/253 reads (15%) | called by muse, mutect2, varscan2
- DNER | c.1455G>C p.V485= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as rs773330572; called by muse, mutect2, varscan2
- DOCK2 | c.1770G>T p.G590= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- DSEL | c.1149G>A p.P383= | Silent (SNP) | VAF 74/326 reads (23%) | catalogued as rs1194935162; called by muse, mutect2, varscan2
- DUSP10 | c.1392C>T p.N464= | Silent (SNP) | VAF 44/349 reads (13%) | catalogued as rs61757363, COSV60459953; called by muse, mutect2, varscan2
- DYRK1B | c.1149G>T p.T383= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- DYSF | c.4665A>T p.P1555= | Silent (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- EFCAB6 | c.1860C>G p.T620= | Silent (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- ERG | c.549C>T p.F183= | Silent (SNP) | VAF 96/470 reads (20%) | catalogued as rs1219744755, COSV55741480; called by muse, mutect2, varscan2
- ETHE1 | c.420C>T p.V140= | Silent (SNP) | VAF 19/226 reads (8%) | catalogued as rs374482389; called by muse, mutect2
- FAM71C | c.390C>T p.I130= | Silent (SNP) | VAF 103/345 reads (30%) | catalogued as rs771838130; called by muse, mutect2, varscan2
- FIGNL1 | c.1452A>G p.A484= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV63553936; called by muse, mutect2, varscan2
- GABRA4 | c.1530T>G p.P510= | Silent (SNP) | VAF 51/345 reads (15%) | catalogued as COSV51926115; called by muse, mutect2, varscan2
- GHRHR | c.213C>A p.G71= | Silent (SNP) | VAF 74/322 reads (23%) | catalogued as rs768112214, COSV58197502; called by muse, mutect2, varscan2
- GP2 | c.828C>A p.T276= (on ENST00000381362 / NM_001007240.3; = p.T273= on NM_001502.4) | Silent (SNP) | VAF 36/264 reads (14%) | catalogued as COSV56892897; called by muse, mutect2, varscan2
- GPR33 | c.729C>A p.P243= | Silent (SNP) | VAF 1248/1598 reads (78%) | called by muse, mutect2, varscan2
- GPR37 | c.567C>A p.L189= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs1279434224, COSV100391182; called by muse, mutect2, varscan2
- GPR88 | c.348G>T p.R116= | Silent (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- GRIA2 | c.1638C>A p.I546= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- HAPLN1 | c.597G>T p.R199= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- HCN3 | c.399T>C p.S133= | Silent (SNP) | VAF 43/367 reads (12%) | called by muse, mutect2, varscan2
- HEPH | c.2043C>A p.T681= (on ENST00000343002; = p.T414= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- HOXD13 | c.270C>T p.S90= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- KCNB2 | c.2256C>A p.I752= | Silent (SNP) | VAF 64/292 reads (22%) | called by muse, mutect2, varscan2
- KIF18B | c.990C>T p.P330= | Silent (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- KIF26B | c.3618C>T p.R1206= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1167897673; called by muse, mutect2, varscan2
- KLF4 | c.204G>T p.A68= | Silent (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- LETM1 | c.1215C>T p.H405= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, varscan2
- LIMCH1 | c.60C>T p.P20= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as rs772963610; called by muse, mutect2, varscan2
- LRRC47 | c.1581C>T p.V527= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- LRRC8B | c.123G>T p.L41= | Silent (SNP) | VAF 71/386 reads (18%) | called by muse, mutect2, varscan2
- LRRC8C | c.1506C>T p.D502= | Silent (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- MAPT | c.660G>T p.L220= (on ENST00000262410 / NM_001377265.1; = p.L145= on NM_016835.4) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99289507; called by muse, mutect2, varscan2
- MC2R | c.834C>T p.F278= | Silent (SNP) | VAF 68/414 reads (16%) | called by muse, mutect2, varscan2
- MET | c.1083C>G p.A361= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1044616410, COSV59257162; called by muse, mutect2, varscan2
- MGAM | c.1281A>G p.S427= | Silent (SNP) | VAF 56/327 reads (17%) | called by muse, mutect2, varscan2
- MROH5 | c.3400C>A p.R1134= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MUC17 | c.11028T>A p.P3676= | Silent (SNP) | VAF 31/115 reads (27%) | called by muse, mutect2, varscan2
- MYH2 | c.3735C>T p.S1245= | Silent (SNP) | VAF 84/287 reads (29%) | called by muse, mutect2, varscan2
- MYLK | c.2574G>A p.Q858= | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- MYO19 | c.2439C>A p.I813= (on ENST00000614623 / NM_001163735.1; = p.I613= on NM_025109.5) | Silent (SNP) | VAF 29/154 reads (19%) | called by muse, mutect2, varscan2
- NAB1 | c.573G>A p.L191= | Silent (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- NBEA | c.4494C>T p.S1498= | Silent (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- NFATC1 | c.1950G>T p.L650= | Silent (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- NFKBIE | c.1173G>A p.R391= (on ENST00000275015; = p.R252= on NM_004556.3) | Silent (SNP) | VAF 29/278 reads (10%) | called by muse, mutect2, varscan2
- NIPBL | c.552A>C p.A184= | Silent (SNP) | VAF 92/396 reads (23%) | called by muse, mutect2, varscan2
- NLRP12 | c.1545G>A p.L515= | Silent (SNP) | VAF 55/486 reads (11%) | called by muse, mutect2, varscan2
- NOX4 | c.732A>G p.S244= | Silent (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- NPBWR2 | c.219G>T p.A73= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV63900054; called by mutect2, varscan2
- NSG2 | c.45G>T p.P15= | Silent (SNP) | VAF 41/214 reads (19%) | catalogued as COSV57458742; called by muse, mutect2, varscan2
- NTAQ1 | c.483G>A p.P161= | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as rs750799018; called by muse, mutect2, varscan2
- OBI1 | c.246G>A p.T82= | Silent (SNP) | VAF 48/255 reads (19%) | catalogued as rs377301991; called by muse, mutect2, varscan2
- OR2W3 | c.642C>A p.I214= | Silent (SNP) | VAF 81/308 reads (26%) | catalogued as COSV64456172; called by muse, varscan2
- OR4C5 | c.66G>A p.L22= | Silent (SNP) | VAF 46/383 reads (12%) | called by muse, mutect2, varscan2
- OR4K5 | c.924A>T p.P308= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, varscan2
- OR4M1 | c.513C>A p.P171= | Silent (SNP) | VAF 36/858 reads (4%) | catalogued as COSV100271008, COSV60062033; called by muse, mutect2
- OR4P4 | c.693C>A p.R231= | Silent (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- OR51M1 | c.120C>T p.F40= | Silent (SNP) | VAF 104/489 reads (21%) | called by muse, mutect2, varscan2
- OSBPL6 | c.1677G>T p.L559= | Silent (SNP) | VAF 76/330 reads (23%) | catalogued as COSV51925715; called by muse, mutect2, varscan2
- OTUD6B | c.825A>G p.G275= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- P2RX5 | c.243T>C p.L81= | Silent (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2, varscan2
- PABPC1 | c.243A>G p.P81= | Silent (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- PAPPA2 | c.705A>T p.P235= | Silent (SNP) | VAF 105/385 reads (27%) | called by muse, mutect2, varscan2
- PASK | c.9C>T p.D3= | Silent (SNP) | VAF 48/258 reads (19%) | catalogued as rs750110681; called by muse, mutect2, varscan2
- PCARE | c.1131C>A p.P377= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100527285, COSV100527772; called by muse, mutect2, varscan2
- PCDHA11 | c.1108C>T p.L370= | Silent (SNP) | VAF 51/261 reads (20%) | catalogued as rs1420926866; called by muse, mutect2, varscan2
- PCDHA3 | c.969G>T p.T323= | Silent (SNP) | VAF 149/604 reads (25%) | catalogued as COSV100793231; called by muse, mutect2, varscan2
- PCDHB15 | c.546T>C p.T182= | Silent (SNP) | VAF 67/288 reads (23%) | called by muse, mutect2, varscan2
- PCNX3 | c.2952C>T p.L984= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs746103397; called by muse, mutect2, varscan2
- PDGFRA | c.2283C>A p.L761= | Silent (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- PFKP | c.1002A>G p.L334= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- PIEZO2 | c.8040G>T p.V2680= | Silent (SNP) | VAF 82/211 reads (39%) | called by muse, mutect2, varscan2
- PIK3CG | c.268C>A p.R90= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as rs778022267, COSV63248617; called by muse, mutect2, varscan2
- PLEKHB2 | c.906C>A p.P302= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58238295; called by muse, mutect2, varscan2
- POLR3E | c.912C>T p.S304= | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as rs1383953030; called by muse, mutect2, varscan2
- POM121L2 | c.2040C>T p.A680= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- POTEC | c.99C>A p.P33= | Silent (SNP) | VAF 162/439 reads (37%) | catalogued as COSV62804302, COSV62804486; called by muse, mutect2, varscan2
- PROB1 | c.963C>A p.R321= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- PRRX1 | c.489C>T p.S163= | Silent (SNP) | VAF 36/345 reads (10%) | called by muse, mutect2, varscan2
- PSKH2 | c.750G>A p.V250= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as rs1442602874; called by muse, mutect2, varscan2
- PSPH | c.21G>A p.L7= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as COSV99303960; called by muse, mutect2
- RENBP | c.411C>T p.Y137= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs782049909; called by muse, mutect2, varscan2
- RTF2 | c.537G>A p.V179= | Silent (SNP) | VAF 39/327 reads (12%) | called by muse, mutect2, varscan2
- RYR2 | c.12741G>T p.A4247= | Silent (SNP) | VAF 75/664 reads (11%) | catalogued as COSV63697754; called by muse, mutect2, varscan2
- SALL3 | c.2556G>A p.S852= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1461937657; called by muse, mutect2, varscan2
- SAMD9L | c.3783A>G p.Q1261= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs1283560740; called by muse, mutect2, varscan2
- SCARF1 | c.702C>T p.S234= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1353637047; called by muse, mutect2, varscan2
- SEMA6B | c.927G>T p.T309= | Silent (SNP) | VAF 46/150 reads (31%) | called by muse, mutect2, varscan2
- SHOX | c.102G>T p.T34= | Silent (SNP) | VAF 59/310 reads (19%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1398T>C p.Y466= | Silent (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
- SLC7A13 | c.420C>A p.A140= | Silent (SNP) | VAF 42/348 reads (12%) | called by muse, mutect2, varscan2
- SPEG | c.3333G>A p.R1111= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV56672771; called by muse, mutect2, varscan2
- SPON1 | c.99C>A p.T33= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as rs1554907660; called by muse, mutect2, varscan2
- SPON1 | c.2388G>A p.K796= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- TGIF2LX | c.561C>A p.A187= | Silent (SNP) | VAF 106/303 reads (35%) | catalogued as COSV52215025, COSV52215194; called by muse, mutect2, varscan2
- TMEM115 | c.345C>T p.F115= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as rs868361120; called by muse, mutect2
- TMEM30B | c.600C>T p.T200= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs1266997351; called by muse, mutect2, varscan2
- TMPPE | c.564G>T p.P188= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- TPSG1 | c.114C>T p.I38= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs767100763; called by muse, mutect2, varscan2
- TRIP11 | c.4140C>T p.T1380= | Silent (SNP) | VAF 68/509 reads (13%) | catalogued as rs764516601; called by muse, mutect2, varscan2
- TTN | c.1230C>A p.A410= | Silent (SNP) | VAF 63/280 reads (23%) | catalogued as COSV100599757; called by muse, mutect2, varscan2
- UBA6 | c.933C>T p.C311= | Silent (SNP) | VAF 37/211 reads (18%) | called by muse, mutect2, varscan2
- VCAN | c.8949C>A p.T2983= | Silent (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- WDFY1 | c.255G>T p.V85= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- ZNF285 | c.1567C>A p.R523= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- ZSCAN1 | c.393C>T p.V131= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs751937817, COSV56608300; called by muse, mutect2, varscan2
- ZWINT | c.789C>T p.F263= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- AARSD1 | chr17:42964455 G>A | 5'Flank (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- AC002519.1 | chr16:31793801 G>A | 3'Flank (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2261C>A | RNA (SNP) | VAF 110/217 reads (51%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.312+43T>C | Intron (SNP) | VAF 56/266 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.-129C>T | 5'UTR (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29715338 G>A | 5'Flank (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- C9orf163 | n.1317A>G | RNA (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- CD46 | c.857-43A>G | Intron (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- CNRIP1 | c.330+57A>G | Intron (SNP) | VAF 54/199 reads (27%) | called by muse, mutect2, varscan2
- CORO6 | c.-153G>A | 5'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- CSF2RB | c.-24G>T | 5'UTR (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- CSMD3 | c.*9C>T | 3'UTR (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2, varscan2
- CSNK1G1 | c.1108-8023A>T | Intron (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- CTAGE11P | n.163G>T | RNA (SNP) | VAF 123/598 reads (21%) | called by muse, mutect2, varscan2
- DHFR | c.-40T>A | 5'UTR (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- DNAH14 | c.2938+1981T>C | Intron (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2
- DSG1 | c.1821+28G>T | Intron (SNP) | VAF 41/370 reads (11%) | catalogued as rs367953417; called by muse, mutect2, varscan2
- EGFEM1P | n.848C>A | RNA (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- EI24P4 | n.1001C>A | RNA (SNP) | VAF 36/324 reads (11%) | called by muse, mutect2, varscan2
- EVC2 | c.*29G>A | 3'UTR (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2, varscan2
- FAM131B | c.90+27C>A | Intron (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- FAM182B | n.544G>A | RNA (SNP) | VAF 89/556 reads (16%) | called by muse, varscan2
- FAM217A | c.-109G>T | 5'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FAM74A3 | n.437A>T | RNA (SNP) | VAF 85/635 reads (13%) | called by muse, mutect2, varscan2
- GPM6A | c.-23+31418C>A | Intron (SNP) | VAF 47/258 reads (18%) | called by muse, mutect2, varscan2
- GSTM1 | c.113-25T>G | Intron (SNP) | VAF 41/159 reads (26%) | called by muse, mutect2, varscan2
- GUSBP10 | n.267G>T | RNA (SNP) | VAF 51/267 reads (19%) | called by muse, mutect2, varscan2
- IGFBP2 | c.672+28G>T | Intron (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- IGKV1D-27 | n.241G>T | RNA (SNP) | VAF 100/411 reads (24%) | catalogued as rs777865225; called by muse, mutect2, varscan2
- KMT2B | c.6960-15G>T | Intron (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- LINC01591 | n.252G>T | RNA (SNP) | VAF 61/174 reads (35%) | called by muse, mutect2, varscan2
- LMO7DN | n.272C>T | RNA (SNP) | VAF 45/298 reads (15%) | catalogued as rs953547910, COSV59090457; called by muse, mutect2, varscan2
- LRRIQ3 | c.*11G>C | 3'UTR (SNP) | VAF 60/220 reads (27%) | catalogued as rs1196156135; called by muse, mutect2, varscan2
- MGAM | c.4618+338G>A | Intron (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- MPPED2 | c.311-9278T>A | Intron (SNP) | VAF 76/364 reads (21%) | called by muse, mutect2, varscan2
- MT1H | c.-6C>A | 5'UTR (SNP) | VAF 37/218 reads (17%) | called by muse, mutect2, varscan2
- NBPF25P | n.1999A>T | RNA (SNP) | VAF 16/508 reads (3%) | called by muse, mutect2
- NDRG1 | chr8:133302016 G>T | 5'Flank (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- NDUFA5 | c.66+121G>T | Intron (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- NFAM1 | c.452-821C>T | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- NME6 | c.194-73G>A | Intron (SNP) | VAF 46/388 reads (12%) | called by muse, mutect2, varscan2
- NOP58 | c.175+203A>T | Intron (SNP) | VAF 83/366 reads (23%) | called by muse, mutect2, varscan2
- NT5C3A | chr7:33062794 C>T | 5'Flank (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- NTRK3 | c.2133+51del | Intron (DEL) | VAF 23/221 reads (10%) | called by mutect2, pindel, varscan2
- OR2A13P | n.573C>T | RNA (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- PAX6 | c.10+13G>T | Intron (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- PAX8 | c.-1G>A | 5'UTR (SNP) | VAF 20/95 reads (21%) | catalogued as rs774204378, COSV54511330; called by muse, mutect2, varscan2
- PEX16 | c.*99G>T | 3'UTR (SNP) | VAF 19/154 reads (12%) | catalogued as rs1239984110; called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3834G>T | RNA (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
- RAB6A | c.129+85A>G | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- RMDN1 | chr8:86468400 T>A | 3'Flank (SNP) | VAF 41/183 reads (22%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159326 C>A | 5'Flank (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- SERTAD4 | c.-18+815G>T | Intron (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- SKA2P1 | n.375C>A | RNA (SNP) | VAF 35/150 reads (23%) | catalogued as rs767304241; called by muse, mutect2, varscan2
- SLC2A11 | c.1086+24G>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as rs1359569053; called by mutect2, varscan2
- SLC6A10P | n.3194C>T | RNA (SNP) | VAF 25/136 reads (18%) | catalogued as rs751890544; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44330G>T | Intron (SNP) | VAF 75/138 reads (54%) | called by muse, varscan2
- SLCO2A1 | chr3:133928391 A>T | 3'Flank (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- SNCAIP | c.1423-451G>A | Intron (SNP) | VAF 69/338 reads (20%) | catalogued as rs753906032; called by muse, mutect2, varscan2
- SNTG1 | c.-14T>A | 5'UTR (SNP) | VAF 22/130 reads (17%) | catalogued as rs769116610; called by muse, mutect2, varscan2
- SQLE | c.-812C>T | 5'UTR (SNP) | VAF 11/77 reads (14%) | catalogued as rs762588821; called by muse, mutect2, varscan2
- TBX5 | c.*29C>A | 3'UTR (SNP) | VAF 82/258 reads (32%) | catalogued as COSV100090800; called by muse, varscan2
- TLL1 | c.1524+1002C>T | Intron (SNP) | VAF 15/170 reads (9%) | catalogued as rs1370141214, COSV50282404; called by muse, mutect2
- TMCO1 | c.*3312G>T | 3'UTR (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- TMEM167B | c.-62C>T | 5'UTR (SNP) | VAF 19/112 reads (17%) | catalogued as rs1331700489; called by muse, mutect2, varscan2
- TMEM217 | c.*105G>A | 3'UTR (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
- TMPRSS3 | c.*216G>A | 3'UTR (SNP) | VAF 40/154 reads (26%) | catalogued as rs748659120; called by muse, mutect2, varscan2
- TP73 | c.186+7707A>T | Intron (SNP) | VAF 9/105 reads (9%) | catalogued as rs1277990226; called by muse, mutect2
- TP73 | c.186+7709A>T | Intron (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- TRIM9 | c.919-28C>A | Intron (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- TSN | c.67-660C>T | Intron (SNP) | VAF 17/126 reads (13%) | catalogued as rs1202689476, COSV67606000; called by muse, mutect2, varscan2
- VAPB | c.*4988A>T | 3'UTR (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37220326 G>T | 3'Flank (SNP) | VAF 36/213 reads (17%) | called by muse, mutect2, varscan2
- WASH8P | n.464G>T | RNA (SNP) | VAF 109/877 reads (12%) | called by muse, mutect2, varscan2
- ZNF117 | c.34+75G>T | Intron (SNP) | VAF 67/292 reads (23%) | called by muse, mutect2, varscan2
- ZNF185 | c.1209-3466G>C | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- ZNF280D | c.381+23G>T | Intron (SNP) | VAF 28/323 reads (9%) | catalogued as COSV50998759; called by muse, mutect2
- ZNF849P | n.1395G>A | RNA (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
